Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6DQ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6DQ-01B (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Distal third of esophagus
QW 5/21/13 C15.5

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) ESOPHAGUS, DISTAL, TUMOR, BIOPSY:
INVASIVE MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA.

GROSS DESCRIPTION

(A) DISTAL ESOPHAGEAL TUMOR – Multiple fragments of tan-pink soft tissue (1.2 x 0.6 x 0.2 cm). Specimen submitted entirely in A.

CLINICAL HISTORY

Esophageal CA.

SNOMED CODES

T-56000, M-81403

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 2]
Page: 2
Specimen Date/Time:

ADDENDUM

This modified report is being issued to report results of immunostain.

Addendum completed by

COMMENT

This addendum is issued to report results of immunostain for Her-2/neu performed on distal esophageal adenocarcinoma.

The tumor cells are immunonegative for Her-2/neu (score 0 of 3).

Entire report and diagnosis completed by:

-----END OF REPORT-----

	Yes	No

Source: NCI Genomic Data Commons file c482f49d-c42d-4d85-9bc5-257af5029172 (TCGA-R6-A6DQ.003A2BE1-B0E1-427B-B44C-655E106F8A4E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).